Gene-level copy-number profile of tumor specimen C3L-00999-01 from CPTAC case C3L-00999, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 56.2 years (20,513 days).
Specimen C3L-00999-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 13ef1eeb-7ce9-4145-8844-23f54a4ed506.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00999-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/895294b0-4d77-4f27-b8ec-dec0fd2847fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,991; copy number 2: 52,717; copy number 3: 3,122; copy number 4: 9; copy number 5: 75; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:27,819,376–27,917,298, 1 gene, copy number 5 (within-gene range 2–5): PLUT.
- chr13:27,920,000–28,138,193, 10 genes, copy number 5–6: PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1.
- chr13:29,764,371–33,350,630, 65 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:33,335,497–33,349,619, 1 gene, copy number 5 (within-gene range 2–5): AL138999.2.

Autosomal genes at a single copy (total copy number 1): 137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
